TCGA case TCGA-AA-3525 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b107565b-7558-4745-952b-689178367e1c

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age: 90 years or older (exact value withheld by GDC); Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.2; Tissue or organ of origin: Ascending colon; Site of resection or biopsy: Hepatic flexure of colon; Classification of tumor: primary; Age at diagnosis: 90 years or older (exact value withheld by GDC); Year of diagnosis: 2007; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1 day.
   Pathology details: Lymph nodes positive: 2; Lymph nodes tested: 28; Lymphatic invasion present: No; Vascular invasion present: No.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the colon (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor.
- Days to follow up: 1 day; Disease response: Tumor Free.

Molecular and laboratory tests
- CEA: 11.14 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-3525-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 1; Shortest dimension: 0.9.
  Slide TCGA-AA-3525-01A-02-BS2: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 30; Percent necrosis: 0; Percent stromal cells: 10.
  Slide TCGA-AA-3525-01A-01-BS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 10.
- Sample TCGA-AA-3525-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-3525-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.
- Sample TCGA-AA-3525-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 0.8; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: With tumor; Anatomic organ subdivision: Hepatic Flexure; Lymph nodes examined: Yes; CEA level pretreatment: 11.14; Lymphovascular invasion indicator: No; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -8886.

GDC annotations on this case (curator notes; quoted as recorded):
- Case submitted is found to be a recurrence after submission: patient had a prior colon malignancy.
- Prior malignancy: Prior malignancy colon cancer. No systemic chemotherapy or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 245 days; disease-specific survival: no event (censored), 245 days; progression-free interval: no event (censored), 245 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-AA-3525-01): tumor purity 0.64, ploidy 2, whole-genome doublings 0 (call status: legacy_call).
